Gene-level copy-number profile of tumor specimen TCGA-L5-A8NS-01A from TCGA case TCGA-L5-A8NS, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 76.1 years (27,800 days).
Specimen TCGA-L5-A8NS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.c9c4a4c4-1f49-4cbe-bece-06822ff306b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NS-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a744f405-d189-4305-b603-0737c919c680

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 177; copy number 2: 7,020; copy number 3: 9,986; copy number 4: 16,032; copy number 5: 20,864; copy number 6: 3,617; copy number 7: 1,174; copy number 8: 622; copy number 9: 302; copy number 11: 3; copy number 12: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NS-01A-12D-A37B-01): tumor purity 0.64, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,039,761–59,063,503, 1 gene: AC092343.1.
- chr5:142,770,377–143,229,011, 1 gene (within-gene range 0–3): ARHGAP26.
- chr5:142,946,569–142,947,105, 1 gene: AC008533.1.
- chr21:34,745,757–34,784,886, 1 gene: LINC01426.
- chr21:34,836,286–34,884,882, 1 gene (within-gene range 0–2): AP000331.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:175,290,731–175,884,021, 9 genes, copy number 12: ARL2BPP6, DRD1, AC091393.2, SFXN1, AC091393.1, RN7SKP148, HRH2, RNU6-226P, CPLX2.
- chr11:87,258,851–87,330,052, 3 genes, copy number 11: AP001102.1, AP000811.1, PSMA2P1.

Autosomal genes at a single copy (total copy number 1): 175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
